Surgical pathology report (de-identified scan), TCGA case TCGA-EY-A54A, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of North Carolina, specimen TCGA-EY-A54A-01A (Primary Tumor).

[page 1 of 7]
ICD-O-3

Adenocarcinoma,
Endometrioid NOS
838013
Site Uterus, corpus +
lower uterine
segment C54.9
12/31/2910

Diagnosis:

A: Lymph nodes, right para-aortic, regional dissection
- One out of six lymph nodes with metastatic adenocarcinoma
(1/6)

B: Lymph nodes, left para-aortic, regional dissection
- Two lymph nodes, no tumor seen, one with focal
endosalpingiosis (0/2)

C: Uterus, cervix, bilateral tubes and ovaries, radical
hysterectomy and
bilateral salpingo-oophorectomy

Histologic type: endometrioid adenocarcinoma

Histologic grade: overall FIGO grade 3 (architectural grade 2,
nuclear grade
3)

Tumor site: anterior and posterior corpus and lower uterine
segment

Myometrial invasion: inner half
Depth: 1.1 cm Wall thickness: 2.7 cm Percent:
41% (C13)

Serosal involvement: absent

Lower uterine segment involvement: present

Cervical involvement: absent

Adnexal involvement: absent

Other involved sites: N/A

Cervical/vaginal margin and distance: widely free of tumor

Lymphovascular space invasion: extensive lymphovascular space
invasion
present, involving inner and outer myometrial wall (eg. C15)

[page 2 of 7]
Regional lymph nodes (see other specimens):

Total number involved: 5

Total number examined: 24

Additional pathologic findings:

- Myometrium shows leiomyomas with hyalinization, largest up to 4.7 cm in diameter

- Cervix shows Nabothian cysts, acute and chronic cervicitis, tubal metaplasia, benign mixed endocervical/ lower uterine segment endometrial polyp

Right ovary:

- Atrophic ovary, no tumor seen

Left ovary:

- Atrophic ovary, no tumor seen

Right fallopian tube:

- Paratubal cysts and remote hematosalpinx, no tumor seen

Left fallopian tube:

- No tumor seen

AJCC Pathologic Stage: pT1b pN2 pMx

FIGO (2009 classification) Stage Grouping: IIIC2

Note: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

D: Lymph nodes, right pelvic, regional dissection

- Three out of seven lymph nodes with metastatic adenocarcinoma (3/7)

E: Lymph nodes, left pelvic, regional dissection

- One out of nine lymph nodes with metastatic adenocarcinoma (1/9)

[page 3 of 7]
Clinical History:

·year-old female with endometrial carcinoma.

Gross Description:

Received are five appropriately labeled containers.

Container A is additionally labeled "lymph node, right para-aortic, regional dissection." Received are two fragments of focally cauterized yellow lobular fibroadipose tissue, 3.5 x 1.9 x 1.0 cm, in aggregate. Three lymph node candidates are identified ranging in largest dimension from 1.5 to 5.9 cm.

Block summary:

A1 - single lymph node candidate with additional fibroadipose tissue

A2,A3??

A4,A5 - serial sections of the largest lymph node candidate,

Container B is additionally labeled "lymph node, left para-aortic, regional dissection." Received is a single unoriented yellow lobular fibrofatty tissue, 3.3 x 1.5 x 0.5 cm. The specimen is serially sectioned and submitted entirely in blocks B1 and B2,

Container C is additionally labeled "uterus, cervix, bilateral tubes, ovaries, hysterectomy and bilateral salpingo-oophorectomy."

Adnexa: present, bilateral

Weight: 305 grams

Shape: pear shaped, globular

Dimensions:

height: 7.0 cm

anterior to posterior width: 6.0 cm

breadth at fundus: 8.0 cm

Serosa: smooth, glistening, focally hemorrhagic

Cervix: The cervix was received separately in the same container, amputated

to the lower uterine segment. The cervix measures

[page 4 of 7]
5.0 x 3.5 x 2.5 cm.

ectocervix: smooth, glistening with peripheral cautery; the os is

distorted, 0.6 cm

endocervix: trabecular with multiple pink/tan polypoid/exophytic lesions

ranging in size from 0.2 cm in diameter to 0.9 x 0.9 cm

length of endocervical canal: The endocervical canal has adherent mucus.

The length of the endocervical canal is 2.8 cm.

Endomyometrium:

length of endometrial cavity: cannot be assessed due to the presence of tumor

width of endometrial cavity at fundus: approximately 3.5 cm (cannot be

accurately assessed due to presence of the tumor)

tumor findings:

dimensions: at least 4.5 x 3.0 cm

appearance: exophytic, pale tan to brown, focally friable

location and extent: The tumor involves the anterior and posterior

corpus and extends to the lower uterine segment where the cervix is separated from the main uterus specimen.

Comment: In the anterior lower uterine segment there is a 1.1 x 0.2 x

0.1 cm endometrial polyp present.

myometrial invasion: inner one-half

thickness of myometrial wall at deepest gross invasion: 1.3 cm

other findings or comments: Throughout the myometrium there are multiple

well circumscribed, white/tan, whorled nodules

ranging in size from 0.2 cm in diameter to 4.7 cm in diameter.

Adnexa:

Right ovary:

dimensions: 3.5 x 1.5 x 0.4 cm

external surface: pale tan, cerebriform

cut surface: pale tan, unremarkable

Right fallopian tube:

dimensions: approximately 6 cm long, 0.8 cm in diameter

other findings: The fimbrial end is adhered to the ovary.

Approximately __ cm from the fimbrial end there are multiple thin

walled paratubal cysts filled with thin serous fluid. The external surface

[page 5 of 7]
of the fallopian tube is pale pink to gray/tan, smooth, unremarkable. The cut surface reveals a lumen with pale tan velvety mucosa.

Left ovary:

dimensions: 2.5 x 1.5 x 0.5 cm

external surface: white/tan, cerebriform

cut surface: pale tan, unremarkable

Left fallopian tube:

dimensions: length is 3.6 cm, diameter is 1.2 cm

other findings: There are multiple thin walled cysts approximately 0.1

to 0.2 cm in diameter throughout the length of the fallopian tube which is blunt on both ends and a fimbrial end is not

identified. The external surface is pink to gray/tan.

Sectioning reveals a lumen with pale tan velvety mucosa and mucoid material.

Lymph nodes: none identified

Other comments: none

Digital photograph taken: not taken

Tissue submitted for special investigations: Tumor is submitted to Tissue Procurement foundation.

Block summary:

C1,C2 - representative section of the anterior cervix and lower uterine

segment at 11 o' clock, bisected

C3,C4 - representative section of the anterior cervix at 12 o' clock, bisected

The above sections include one of the polypoid lesions in the cervix.

C5 - representative section of the anterior cervix at 2 o' clock

C6,C7 - representative section of the cervix and lower uterine segment at 5

o' clock, bisected

C8,C9 - representative sections of the lower uterine segment and cervix at 6

[page 6 of 7]
o' clock, bisected
C10 - anterior upper corpus
C11 - anterior middle corpus
C12 - anterior lower uterine segment, includes the endometrial polyp and myometrial nodule
C13,C14 - posterior upper uterine segment, bisected
C15 - posterior mid corpus
C16 - posterior lower uterine segment
C17 - endometrium with the representative section of largest myometrial nodule
C18 - representative sections from the largest myometrial nodule
C19 - representative sections of the right ovary
C20 - representative cross sections of the right fallopian tube, longitudinal section of fimbrial end
C21 - representative sections of the left ovary
C22 - representative cross sections of the left fallopian tube

Container D is additionally labeled "lymph node, right pelvic, regional dissection." Received is a single unoriented yellow lobular fibroadipose tissue fragment, 5.9 x 3.5 x 0.7 cm. Seven lymph node candidates are identified, ranging in size from 0.4 cm in diameter to 2.0 x 1.5 x 0.5 cm.

Block Summary:

D1 - single lymph node candidate
D2 - single lymph node candidate, bisected
D3 - single lymph node candidate, bisected
D4 - single lymph node candidate, bisected
D5 - single lymph node candidate, bisected
D6 - single lymph node candidate, bisected
D7 - single lymph node candidate, bisected
D8 - remaining fibroadipose tissue

Container E is additionally labeled "lymph node, left pelvic, regional dissection." Received is a single unoriented 3.5 x 3.5 x 1.0 cm yellow lobular soft tissue fragment. Six lymph node candidates are identified ranging in size from 0.4 cm in diameter to 2.5 cm in largest dimension.

[page 7 of 7]
Block summary:

- E1 - two lymph node candidates
- E2 - two lymph node candidates
- E3 - single lymph node candidate, bisected
- E4 - single lymph node candidate, bisected
- E5-E7 - additional fibroadipose tissue,

Source: NCI Genomic Data Commons file 497b5c10-9b17-4e4d-ae45-b8d8a6abb7f1 (TCGA-EY-A54A.E3C3D3B8-550A-4652-9B17-122BC64A437A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).